Somatic mutation profile of tumor specimen 0DMCR7 from CCDI case PBBYNN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 9.4 years (3,424 days).
Specimen 0DMCR7: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 393bfbd1-908a-4b77-ad52-ed973b7ab305.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMCR8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8da47745-6f27-41a0-9168-e464a5fdee88

The open-access MAF lists 50 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, 3'UTR 3, Intron 3, Nonsense Mutation 2, Splice Region 1, Splice Site 1, 5'Flank 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH11 | c.11111G>A p.C3704Y | Missense Mutation (SNP) | VAF 17/562 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100179935; called by muse, mutect2
- IL1RAPL2 | c.1621A>T p.S541C | Missense Mutation (SNP) | VAF 23/906 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV61155311; called by muse, mutect2
- MUC12 | c.2783G>A p.R928H (on ENST00000379442; = p.R785H on NM_001164462.1) | Missense Mutation (SNP) | VAF 18/518 reads (3%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.517); catalogued as rs1251575834, COSV65203379; called by muse, mutect2
- OPRD1 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 296/1078 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.298); catalogued as rs377388458, COSV52379979, COSV52382132; called by muse, mutect2, varscan2
- OR2V2 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 48/708 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs147476494, COSV100080028; called by muse, mutect2
- PRR23A | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 258/557 reads (46%) | SIFT tolerated (0.45); PolyPhen benign (0.068); catalogued as rs531909017, COSV67214056; called by muse, mutect2, varscan2
- SHB | c.1011C>G p.D337E | Missense Mutation (SNP) | VAF 30/660 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV66629762; called by muse, mutect2
- TSPOAP1 | c.5113C>T p.R1705W | Missense Mutation (SNP) | VAF 48/830 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs755682288; called by muse, mutect2
- ZNF280A | c.1501G>A p.G501R | Missense Mutation (SNP) | VAF 461/930 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.045); catalogued as rs367963296; called by muse, mutect2, varscan2
- ZNF589 | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 358/798 reads (45%) | catalogued as rs201102577; called by muse, mutect2, varscan2
- ZNF785 | c.754G>C p.G252R | Missense Mutation (SNP) | VAF 30/680 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101235773; called by muse, mutect2
- ARHGAP20 | c.2720T>C p.I907T | Missense Mutation (SNP) | VAF 66/572 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- BACH1 | c.1078A>G p.T360A | Missense Mutation (SNP) | VAF 50/967 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- C4orf54 | c.3505G>C p.E1169Q | Missense Mutation (SNP) | VAF 236/512 reads (46%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CFAP65 | c.1434C>A p.N478K | Missense Mutation (SNP) | VAF 151/684 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CREBBP | c.6593_6598del p.L2198_Q2199del | In Frame Del (DEL) | VAF 66/638 reads (10%) | called by pindel, varscan2
- CRYZ | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 177/667 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSPG4 | c.3220C>A p.P1074T | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- DSEL | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 133/1084 reads (12%) | called by muse, mutect2, varscan2
- EPS15 | c.2077C>A p.P693T | Missense Mutation (SNP) | VAF 116/1012 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ETHE1 | c.40A>T p.S14C | Missense Mutation (SNP) | VAF 74/527 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FBXW11 | c.703T>G p.C235G | Missense Mutation (SNP) | VAF 216/492 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM8 | c.1383T>A p.F461L | Missense Mutation (SNP) | VAF 377/644 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- HOXB4 | c.576G>T p.R192S | Missense Mutation (SNP) | VAF 36/1209 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KANK4 | c.139G>C p.E47Q | Missense Mutation (SNP) | VAF 83/720 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH5 | c.1531T>A p.S511T | Missense Mutation (SNP) | VAF 30/712 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); called by muse, mutect2
- KLHL42 | c.1280A>T p.Q427L | Missense Mutation (SNP) | VAF 147/696 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- LRRC17 | c.772+1G>T p.X258_splice | Splice Site (SNP) | VAF 15/587 reads (3%) | called by muse, mutect2
- NWD2 | c.1510T>C p.S504P | Missense Mutation (SNP) | VAF 81/604 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- RYR2 | c.6024A>T p.G2008= | Splice Region (SNP) | VAF 146/765 reads (19%) | called by muse, mutect2, varscan2
- RYR3 | c.4771T>A p.Y1591N | Missense Mutation (SNP) | VAF 282/592 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- TRIM26 | c.388C>A p.H130N | Missense Mutation (SNP) | VAF 84/669 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZFC3H1 | c.1507T>G p.S503A | Missense Mutation (SNP) | VAF 39/606 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.281); called by muse, mutect2
- DLX3 | c.246C>G p.P82= | Silent (SNP) | VAF 58/782 reads (7%) | called by muse, mutect2
- DNAAF6 | c.384G>A p.G128= | Silent (SNP) | VAF 23/466 reads (5%) | catalogued as rs763547239; called by muse, mutect2
- ERMARD | c.1365C>T p.F455= | Silent (SNP) | VAF 63/420 reads (15%) | called by muse, mutect2, varscan2
- KRT37 | c.1266G>A p.T422= | Silent (SNP) | VAF 216/712 reads (30%) | catalogued as rs973106401; called by muse, mutect2, varscan2
- MYH14 | c.4344C>T p.D1448= | Silent (SNP) | VAF 163/552 reads (30%) | catalogued as rs746379075; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRICKLE3 | c.654T>C p.C218= | Silent (SNP) | VAF 227/514 reads (44%) | called by muse, mutect2, varscan2
- RRS1 | c.243G>T p.T81= | Silent (SNP) | VAF 82/932 reads (9%) | called by muse, mutect2
- SERPINE1 | c.279C>T p.G93= | Silent (SNP) | VAF 99/537 reads (18%) | called by muse, mutect2, varscan2
- TTLL6 | c.2004G>A p.K668= (on ENST00000393382 / NM_001130918.3; = p.K361= on NM_173623.3) | Silent (SNP) | VAF 62/864 reads (7%) | catalogued as rs1326933808, COSV64976366; called by muse, mutect2
- ABCA10 | c.4398-92A>T | Intron (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- DOCK8 | c.53+431G>T | Intron (SNP) | VAF 59/316 reads (19%) | called by muse, mutect2, varscan2
- KPNB1 | c.2353+94T>A | Intron (SNP) | VAF 18/142 reads (13%) | called by muse, mutect2
- KRTAP1-1 | c.-15T>A | 5'UTR (SNP) | VAF 69/541 reads (13%) | called by muse, mutect2, varscan2
- PGM2 | c.*18T>A | 3'UTR (SNP) | VAF 16/601 reads (3%) | called by muse, mutect2
- TMEM182 | c.*28G>C | 3'UTR (SNP) | VAF 56/647 reads (9%) | catalogued as COSV101305434; called by muse, mutect2
- TMPO | c.*19G>C | 3'UTR (SNP) | VAF 30/484 reads (6%) | catalogued as COSV58462466; called by muse, mutect2
- ZC3H14 | chr14:88563035 G>A | 5'Flank (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
